Somatic mutation profile of tumor specimen TCGA-WQ-A9G7-01A (aliquot TCGA-WQ-A9G7-01A-11D-A36X-10) from TCGA case TCGA-WQ-A9G7, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G3.
Specimen TCGA-WQ-A9G7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b39991cd-ef89-4e1a-83d1-dadb46ef3eb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WQ-A9G7-10A (Blood Derived Normal), aliquot TCGA-WQ-A9G7-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61f674f5-5fb3-47f8-8ff2-2d44e236f8f2

The open-access MAF lists 582 somatic variants for this specimen: 420 protein-altering or splice-affecting, 154 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 297, Silent 154, Frame Shift Del 62, Frame Shift Ins 27, Nonsense Mutation 11, In Frame Del 9, Splice Site 8, Splice Region 6, Intron 3, 3'Flank 2, RNA 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.1358_1359del p.K453Rfs*15 | Frame Shift Del (DEL) | VAF 22/53 reads (42%) | catalogued as rs1351986946; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AATK | c.1184T>C p.L395P (on ENST00000326724 / NM_001080395.3; = p.L292P on NM_004920.2) | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100452732; called by muse, mutect2, varscan2
- ABCA9 | c.1275C>T p.P425= | Splice Region (SNP) | VAF 39/252 reads (15%) | catalogued as rs146940647; called by muse, mutect2, varscan2
- ABCC9 | c.4319C>T p.A1440V | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs767586816, COSV53973961, COSV53978051; called by muse, mutect2, varscan2
- ABCE1 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99668507; called by muse, mutect2, varscan2
- ABHD16B | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1320411516, COSV99410618; called by muse, mutect2, varscan2
- ABTB1 | c.435C>G p.D145E (on ENST00000232744 / NM_172027.3; = p.D3E on NM_032548.3) | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99229703; called by muse, mutect2, varscan2
- ACTL6A | c.523A>G p.T175A | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); catalogued as COSV101199654; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1342197038, COSV58444407; called by muse, mutect2, varscan2
- ADD1 | c.1605+1G>A p.X535_splice | Splice Site (SNP) | VAF 25/96 reads (26%) | catalogued as COSV99296295; called by muse, mutect2, varscan2
- ADGRB2 | c.3062C>T p.S1021F | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99925994; called by muse, mutect2
- ADGRG4 | c.5324A>G p.K1775R | Missense Mutation (SNP) | VAF 88/317 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV99795095; called by muse, mutect2, varscan2
- ADRA2B | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.581); catalogued as rs370956755; called by muse, mutect2, varscan2
- AFF3 | c.1140A>T p.E380D | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV100418516; called by muse, mutect2, varscan2
- AHCTF1 | c.3885del p.K1295Nfs*11 (on ENST00000366508; = p.K1269Nfs*11 on NM_015446.5) | Frame Shift Del (DEL) | VAF 26/242 reads (11%) | catalogued as COSV58251593; called by mutect2, varscan2
- AIM2 | c.959del p.N320Mfs*7 | Frame Shift Del (DEL) | VAF 35/120 reads (29%) | catalogued as rs752653022, COSV63698332; called by mutect2, pindel, varscan2
- AKAP17A | c.430del p.E144Sfs*18 | Frame Shift Del (DEL) | VAF 23/152 reads (15%) | catalogued as COSV58308392; called by pindel, varscan2
- ALS2 | c.1409T>C p.I470T | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV99969086; called by muse, mutect2, varscan2
- AMBRA1 | c.2638G>A p.V880M (on ENST00000458649 / NM_001367468.1; = p.V790M on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs377069728; called by muse, mutect2, varscan2
- ANK1 | c.4667A>G p.E1556G | Missense Mutation (SNP) | VAF 274/1195 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs1255242079, COSV99224745; called by muse, varscan2
- ANKFN1 | c.1782G>T p.Q594H | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100593332; called by muse, mutect2, varscan2
- AOC2 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs267604890, COSV53827971; called by muse, mutect2, varscan2
- AP3B2 | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55616752; called by muse, mutect2, varscan2
- APAF1 | c.1805del p.N602Tfs*8 (on ENST00000551964 / NM_181861.2; = p.N591Tfs*8 on NM_001160.3) | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | catalogued as rs758129366; called by mutect2, varscan2
- APBA1 | c.713A>G p.Y238C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV99595817; called by muse, mutect2
- APOC1 | c.112A>G p.K38E | Missense Mutation (SNP) | VAF 65/458 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.932); catalogued as rs778438750, COSV99377172; called by muse, varscan2
- ARFGEF1 | c.2993C>T p.A998V | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99141335; called by muse, mutect2, varscan2
- ARHGAP22 | c.1097G>T p.C366F | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.332); catalogued as COSV99984963; called by muse, mutect2, varscan2
- ARHGEF11 | c.3230C>T p.A1077V | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs527422829, COSV100168457; called by muse, mutect2, varscan2
- ARHGEF2 | c.1894G>A p.A632T (on ENST00000361247 / NM_001162383.2; = p.A604T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV58107366; called by muse, mutect2, varscan2
- ASCC3 | c.1200A>G p.I400M | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.143); catalogued as COSV100225522; called by muse, mutect2, varscan2
- ASPRV1 | c.458T>C p.L153P | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781731211, COSV100208458, COSV57228197; called by muse, mutect2, varscan2
- ATF7IP | c.2926A>T p.S976C | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.719); catalogued as COSV99661459; called by muse, mutect2, varscan2
- ATP11B | c.3386C>T p.A1129V | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); catalogued as rs777176110, COSV100017680; called by muse, mutect2, varscan2
- ATP2A3 | c.1780G>A p.V594M | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs745362732, COSV99989019; called by muse, mutect2, varscan2
- B4GALNT3 | c.2888G>A p.R963K | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99842779; called by muse, mutect2, varscan2
- BARHL2 | c.173T>C p.V58A | Missense Mutation (SNP) | VAF 22/237 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.956); catalogued as COSV100966043; called by muse, mutect2, varscan2
- BAZ1B | c.2222C>T p.T741M | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs201259773, COSV59995535; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 24/106 reads (23%) | catalogued as rs768244116; called by mutect2, varscan2
- BLM | c.2268dup p.D757Rfs*18 | Frame Shift Ins (INS) | VAF 62/262 reads (24%) | catalogued as rs747341586; called by mutect2, varscan2
- BOP1 | c.106dup p.L36Pfs*34 | Frame Shift Ins (INS) | VAF 16/85 reads (19%) | catalogued as rs782133829; called by mutect2, varscan2
- BPTF | c.6132A>G p.K2044= | Splice Region (SNP) | VAF 23/207 reads (11%) | catalogued as COSV100074619; called by muse, mutect2, varscan2
- C16orf70 | c.1262T>C p.L421P | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV99531260; called by muse, mutect2, varscan2
- C1GALT1C1 | c.855G>C p.Q285H | Missense Mutation (SNP) | VAF 105/324 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV100485603; called by muse, mutect2, varscan2
- C1orf87 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100966994; called by muse, mutect2, varscan2
- C4A | c.3387+2T>A p.X1129_splice | Splice Site (SNP) | VAF 16/562 reads (3%) | catalogued as COSV101418324; called by muse, mutect2
- C5orf38 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV100121669; called by muse, mutect2, varscan2
- CABLES1 | c.508C>A p.L170M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.201); catalogued as COSV99908486; called by muse, mutect2
- CACNA1C | c.3589C>T p.R1197W | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs888326149, COSV100214323; called by muse, mutect2, varscan2
- CACNA1F | c.1494C>T p.C498= | Splice Region (SNP) | VAF 5/85 reads (6%) | catalogued as COSV100544624; called by muse, mutect2
- CACTIN | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as rs1295643587, COSV99698406; called by muse, mutect2
- CAD | c.2299G>A p.G767S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV99254818; called by muse, mutect2, varscan2
- CAPN6 | c.1309C>T p.H437Y | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100136812; called by muse, mutect2, varscan2
- CAPS2 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs764447136, COSV60826315; called by muse, mutect2, varscan2
- CARD18 | c.227T>A p.L76H | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101596026; called by muse, mutect2
- CARMIL2 | c.1855A>G p.N619D | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100576029; called by muse, mutect2, varscan2
- CATSPERD | c.2360G>A p.R787H | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs556362293, COSV58465147; called by muse, mutect2, varscan2
- CCDC159 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs568175380, COSV99264354; called by muse, varscan2
- CCDC87 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs761906517, COSV59578719; called by muse, mutect2, varscan2
- CCNG1 | c.782A>C p.N261T | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as COSV100243563; called by muse, mutect2, varscan2
- CD55 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV100132376; called by muse, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 35/105 reads (33%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC42EP1 | c.289dup p.R97Pfs*78 | Frame Shift Ins (INS) | VAF 36/148 reads (24%) | catalogued as rs762035931; called by mutect2, varscan2
- CDC42EP1 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99312432; called by muse, mutect2, varscan2
- CDC7 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 32/162 reads (20%) | catalogued as rs1406898199, COSV52309379; called by muse, mutect2, varscan2
- CDON | c.23T>C p.L8S | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV99701084; called by muse, mutect2
- CEBPZ | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as COSV99305148; called by muse, mutect2, varscan2
- CENPB | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.627); catalogued as COSV100713375; called by muse, mutect2
- CENPF | c.7897G>A p.A2633T | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100871634; called by muse, mutect2, varscan2
- CENPJ | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs777755478, COSV101121495; called by muse, mutect2, varscan2
- CHD3 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100391021; called by muse, mutect2, varscan2
- CHI3L2 | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100869278; called by muse, mutect2, varscan2
- CHRD | c.2390C>T p.T797M | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs763703209, COSV52608675; called by muse, mutect2, varscan2
- CHRDL2 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765250083, COSV55222629; called by muse, mutect2, varscan2
- CHST13 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100081086; called by muse, mutect2, varscan2
- CLMN | c.2800G>A p.A934T | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.485); catalogued as rs145504462, COSV54183653; called by muse, mutect2, varscan2
- CLSTN3 | c.2606G>A p.R869H | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs575113186, COSV99866797; called by muse, mutect2, varscan2
- CNRIP1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1238563543, COSV99721176; called by muse, mutect2, varscan2
- CNTN5 | c.3133G>A p.V1045I | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs1156878491, COSV54330813; called by muse, mutect2, varscan2
- COL5A1 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs375600865, COSV65664570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A2 | c.2741_2743del p.F914del | In Frame Del (DEL) | VAF 8/78 reads (10%) | catalogued as rs746930351; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- CSNK1A1 | c.145T>C p.S49P | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.068); catalogued as COSV99939426; called by muse, mutect2, varscan2
- CTNNA2 | c.1039A>G p.S347G | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.626); catalogued as COSV100783080; called by muse, mutect2, varscan2
- CUBN | c.2203G>A p.V735I | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370770104; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL9 | c.4340-2A>C p.X1447_splice | Splice Site (SNP) | VAF 26/92 reads (28%) | catalogued as rs1364960889, COSV99335163; called by muse, mutect2, varscan2
- CUL9 | c.5485G>A p.G1829R | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs747458428, COSV99335165; called by muse, mutect2, varscan2
- CWF19L2 | c.1414A>T p.T472S | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV99978730; called by muse, mutect2, varscan2
- CXXC1 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs754927781, COSV53273952; called by muse, mutect2, varscan2
- DAAM2 | c.2698C>T p.R900C (on ENST00000274867 / NM_001201427.2; = p.R899C on NM_015345.3) | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1047541318, COSV51313148; called by muse, mutect2, varscan2
- DCAF12L1 | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100948211; called by muse, mutect2
- DCDC1 | c.748del p.I250Lfs*7 | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | catalogued as rs1565584055; called by mutect2, pindel, varscan2
- DCT | c.555dup p.V186Cfs*9 | Frame Shift Ins (INS) | VAF 11/62 reads (18%) | catalogued as rs762895555; called by mutect2, varscan2
- DDR1 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.32); catalogued as rs145280414; called by muse, mutect2, varscan2
- DENND4B | c.304dup p.L102Pfs*3 | Frame Shift Ins (INS) | VAF 20/146 reads (14%) | catalogued as rs747842790; called by mutect2, varscan2
- DEPDC1 | c.1064dup p.N355Kfs*9 | Frame Shift Ins (INS) | VAF 20/68 reads (29%) | catalogued as rs760464782; called by mutect2, varscan2
- DHRS9 | c.669dup p.L224Tfs*21 | Frame Shift Ins (INS) | VAF 37/128 reads (29%) | catalogued as rs756920263; called by mutect2, varscan2
- DHX15 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 27/97 reads (28%) | catalogued as COSV100391295; called by muse, mutect2, varscan2
- DHX32 | c.1916T>G p.L639* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as COSV99501526; called by muse, mutect2, varscan2
- DLK1 | c.650G>A p.C217Y | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100375152; called by muse, mutect2, varscan2
- DNAAF3 | c.302C>T p.P101L (on ENST00000524407 / NM_001256715.2; = p.P148L on NM_178837.4) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs1428700667, COSV101200130; called by muse, mutect2
- DNAH1 | c.2650C>T p.R884W | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs182989782; called by muse, mutect2, varscan2
- DNAH17 | c.2584T>C p.Y862H | Missense Mutation (SNP) | VAF 112/296 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101101939; called by muse, mutect2, varscan2
- DTX1 | c.1780G>A p.G594S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99921595; called by muse, mutect2, varscan2
- ECH1 | c.539C>T p.T180I | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99669521; called by muse, mutect2, varscan2
- ELAC2 | c.2039C>T p.A680V | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99310468; called by muse, mutect2, varscan2
- ENOX2 | c.1815G>T p.E605D (on ENST00000338144 / NM_001382520.1; = p.E576D on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/313 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV100584012; called by muse, mutect2
- EPB41L5 | c.802del p.W268Gfs*4 | Frame Shift Del (DEL) | VAF 25/95 reads (26%) | catalogued as rs35675992; called by mutect2, pindel, varscan2
- ESPNL | c.2320C>T p.R774W | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs865881007, COSV100547721; called by muse, mutect2
- ESX1 | c.504G>A p.A168= | Splice Region (SNP) | VAF 45/152 reads (30%) | catalogued as COSV65424447; called by muse, mutect2, varscan2
- EYA1 | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs267601985, COSV58168060; called by muse, mutect2, varscan2
- FAM160B2 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs774274007, COSV57157199; called by muse, mutect2, varscan2
- FAM217A | c.1198_1200del p.D400del | In Frame Del (DEL) | VAF 30/170 reads (18%) | catalogued as rs760518162; called by mutect2, pindel, varscan2
- FAM47A | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs758963950, COSV60494403; called by muse, mutect2, varscan2
- FAM9A | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.198); catalogued as rs764416645, COSV101121332; called by muse, mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 53/178 reads (30%) | catalogued as rs748967872; called by mutect2, varscan2
- FCGBP | c.4733C>T p.A1578V | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV99661806; called by muse, mutect2, varscan2
- FGFR4 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777645394, COSV99449475; called by muse, mutect2, varscan2
- FMN2 | c.4237G>A p.E1413K | Missense Mutation (SNP) | VAF 32/334 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as rs768348163, COSV60425877; called by muse, mutect2
- FMNL3 | c.2588G>C p.S863T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.147); catalogued as COSV99525932; called by muse, mutect2, varscan2
- FOXD3 | c.281del p.G94Afs*46 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs1453047553; called by mutect2, pindel
- FRMD8 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs746885699, COSV58212503; called by muse, varscan2
- FUOM | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.11); catalogued as COSV53370424, COSV99529394; called by muse, mutect2, varscan2
- FUT7 | c.721T>A p.F241I | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV99687381; called by muse, mutect2
- GABRR3 | c.748A>G p.S250G | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101512274; called by muse, mutect2, varscan2
- GBP7 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.1); catalogued as COSV54008415, COSV99643597; called by muse, mutect2
- GDPGP1 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV100292032; called by muse, mutect2, varscan2
- GLB1L2 | c.512T>C p.V171A | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); catalogued as rs1170549015, COSV100335260; called by muse, mutect2, varscan2
- GLUD2 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 88/505 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100046711; called by muse, mutect2, varscan2
- GPATCH2 | c.959C>A p.P320H | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100861372; called by muse, mutect2, varscan2
- GRIN2A | c.3064C>T p.R1022C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs560057284, COSV58020945, COSV58030818; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- GRIN2C | c.1586C>T p.T529M | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769299994, COSV53118107; called by muse, mutect2
- GRIPAP1 | c.583A>G p.K195E | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as COSV100904253; called by muse, mutect2, varscan2
- GRSF1 | c.377T>C p.L126P | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99635641; called by muse, mutect2, varscan2
- GSG1L | c.527C>T p.A176V (on ENST00000447459 / NM_001109763.2; = p.A21V on NM_144675.2) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs141366433; called by muse, mutect2, varscan2
- GTPBP2 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as rs754279234, COSV100199904; called by muse, mutect2, varscan2
- HDAC4 | c.979-2A>G p.X327_splice | Splice Site (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100613142; called by muse, mutect2, varscan2
- HEPH | c.3244G>A p.A1082T (on ENST00000343002; = p.A815T on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/271 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as COSV100294597; called by muse, mutect2, varscan2
- HHIPL2 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.481); catalogued as rs377410734, COSV100596740; called by muse, mutect2
- HIRA | c.2336C>T p.T779I | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.129); catalogued as COSV99600132; called by muse, mutect2
- HMCN1 | c.10792A>G p.T3598A | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54896954, COSV99627277; called by muse, mutect2, varscan2
- HMCN1 | c.15396C>A p.C5132* | Nonsense Mutation (SNP) | VAF 7/100 reads (7%) | catalogued as COSV99627281; called by muse, mutect2
- HNRNPF | c.279G>A p.M93I | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV100563006; called by muse, mutect2, varscan2
- HS2ST1 | c.656C>A p.P219Q | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63348997, COSV63349081; called by muse, mutect2, varscan2
- HSD3B1 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 96/184 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs761719743, COSV99347821; called by muse, mutect2, varscan2
- HTT | c.3851A>G p.Q1284R | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.165); catalogued as COSV100750630; called by muse, mutect2, varscan2
- HYOU1 | c.1112A>G p.E371G | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV101345567; called by muse, mutect2, varscan2
- IDUA | c.1361T>G p.V454G | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.067); catalogued as COSV99925829; called by muse, mutect2
- IFT52 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768728172, COSV100887570; called by mutect2, varscan2
- IGSF8 | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs774161453, COSV100081610; called by muse, mutect2, varscan2
- IGSF9 | c.1301G>A p.R434Q (on ENST00000368094 / NM_001135050.2; = p.R418Q on NM_020789.4) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs376059608, COSV100829665, COSV63642454; called by muse, mutect2, varscan2
- IKBKB | c.1612A>G p.M538V | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.074); catalogued as COSV100645654; called by muse, mutect2, varscan2
- IL12RB2 | c.1916G>A p.G639D | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1282492738, COSV99254933; called by muse, mutect2, varscan2
- ILDR2 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV99613594; called by muse, mutect2, varscan2
- INTS3 | c.2699G>A p.S900N | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99669874; called by muse, mutect2, varscan2
- ITM2C | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as rs200829583; called by muse, mutect2, varscan2
- IVL | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV100908144; called by muse, mutect2, varscan2
- JUN | c.967A>G p.M323V | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV100973405; called by muse, varscan2
- KALRN | c.8155dup p.M2719Nfs*27 (on ENST00000360013 / NM_001024660.4; = p.M1022Nfs*27 on NM_007064.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 41/132 reads (31%) | catalogued as rs1249367467; called by mutect2, varscan2
- KCNAB3 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); catalogued as rs1300908380, COSV100366434; called by muse, mutect2
- KCNH2 | c.3403C>T p.R1135C | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.973); catalogued as rs781369850, COSV51215862; called by muse, mutect2, varscan2
- KCNH4 | c.2489G>A p.G830D | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99237006; called by muse, mutect2, varscan2
- KCNJ14 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99474324; called by mutect2, varscan2
- KCNT2 | c.2562C>A p.D854E | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV54096689; called by muse, mutect2
- KDELR1 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100416423; called by muse, mutect2, varscan2
- KDF1 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100264437; called by muse, mutect2, varscan2
- KDM4C | c.3116T>C p.V1039A | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV101184765; called by muse, mutect2
- KIAA1549L | c.2432C>T p.T811M (on ENST00000321505; = p.T1108M on NM_012194.3) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs774799305, COSV99683151; called by muse, mutect2
- KIF14 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs116130210, COSV100950946; called by muse, mutect2, varscan2
- KIF3A | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV101109297; called by muse, mutect2
- KLB | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 21/81 reads (26%) | catalogued as rs190507569; called by muse, mutect2, varscan2
- KLF12 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.795); catalogued as rs750839981, COSV100888446; called by muse, mutect2, varscan2
- KLHL35 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.019); catalogued as COSV100409230; called by muse, mutect2, varscan2
- KLHL42 | c.736T>C p.Y246H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.985); catalogued as COSV101179727; called by muse, mutect2, varscan2
- KPRP | c.224A>G p.Q75R | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV100908684; called by muse, mutect2, varscan2
- KRTAP13-2 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.56); catalogued as rs202124632; called by muse, mutect2
- LAMA5 | c.8608C>T p.R2870W | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs760209781, COSV99439125; called by muse, mutect2, varscan2
- LCORL | c.595A>G p.N199D | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.156); catalogued as COSV100481683; called by muse, mutect2, varscan2
- LIPK | c.965C>T p.T322I | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.38); catalogued as rs200951684, COSV101344970; called by muse, mutect2, varscan2
- LRFN2 | c.1723G>A p.V575M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.311); catalogued as COSV100599393; called by muse, mutect2, varscan2
- LRP1B | c.7248T>A p.N2416K | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV101255048, COSV101257999; called by muse, mutect2, varscan2
- LRP5 | c.3955G>A p.G1319S | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs968164869, COSV99591748; called by muse, mutect2
- LSM14A | c.230T>A p.V77D | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV101471679; called by muse, mutect2, varscan2
- MAST3 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as rs368179436; called by muse, mutect2
- MBNL1 | c.846G>T p.E282D | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as COSV99220079; called by muse, mutect2, varscan2
- MCMDC2 | c.1055A>T p.D352V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100551849; called by muse, mutect2, varscan2
- MCTP2 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs760560583, COSV59149850; called by muse, mutect2, varscan2
- MEN1 | c.307C>A p.L103M | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as CD972306, COSV100198086; called by muse, mutect2, varscan2
- METTL6 | c.593T>G p.L198R | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV101085020; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs762448666; called by pindel, varscan2
- MMS22L | c.1202A>G p.Q401R | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV99246502; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1966del p.M656Cfs*24 | Frame Shift Del (DEL) | VAF 108/398 reads (27%) | catalogued as COSV54914385; called by mutect2, pindel, varscan2
- MSANTD4 | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV100108567; called by muse, mutect2, varscan2
- MTMR4 | c.765T>G p.I255M | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100050941; called by muse, mutect2, varscan2
- MTNR1B | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.633); catalogued as rs1347056510, COSV57065276, COSV57065382; called by muse, mutect2, varscan2
- MUC4 | c.13903G>A p.V4635M (on ENST00000463781 / NM_018406.7; = p.V399M on NM_004532.6) | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.272); catalogued as rs111517228; called by muse, mutect2
- MYO18B | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1483990582, COSV100123217, COSV59152259; called by muse, mutect2, varscan2
- N4BP3 | c.1508A>G p.Y503C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99200640; called by muse, mutect2, varscan2
- NDC1 | c.1002C>A p.D334E | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99323485; called by muse, mutect2, varscan2
- NDUFB5 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1177470494, COSV99372511; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 34/120 reads (28%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NEURL1 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV63913938; called by muse, mutect2, varscan2
- NF2 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs765540111, CM942127, COSV58520023; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NKAPD1 | c.504dup p.Q169Tfs*18 (on ENST00000280352 / NM_001082970.2; = p.Q170Tfs*18 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 78/359 reads (22%) | catalogued as rs757462125; called by mutect2, pindel, varscan2
- NOTCH1 | c.2492C>T p.A831V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs761406127, COSV53032853; called by muse, mutect2, varscan2
- NR2F1 | c.647T>C p.I216T | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100504613; called by muse, mutect2, varscan2
- OCRL | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 152/491 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1441211795, COSV100843392; called by muse, mutect2, varscan2
- ODF3L2 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs1207964519, COSV99198968; called by muse, mutect2, varscan2
- OGDHL | c.2255G>A p.G752D | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934249; called by muse, mutect2, varscan2
- OR1L8 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs144149024; called by muse, mutect2, varscan2
- OR2T4 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 70/566 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.337); catalogued as rs979963875, COSV63544003; called by muse, varscan2
- OR4D5 | c.140T>A p.V47D | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV100189858; called by muse, mutect2, varscan2
- OR52E8 | c.881C>A p.P294H | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV101190132, COSV66207325; called by muse, mutect2, varscan2
- OR52L1 | c.407T>C p.M136T | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100175971, COSV100176126; called by muse, mutect2
- OR5AR1 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.366); catalogued as rs1005880593, COSV100265629; called by muse, mutect2, varscan2
- OR5H14 | c.838G>T p.V280F | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV101454132; called by muse, mutect2, varscan2
- OR6B2 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53156565; called by muse, mutect2, varscan2
- OSBPL3 | c.1885G>A p.V629I | Missense Mutation (SNP) | VAF 152/494 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100513920; called by muse, mutect2, varscan2
- PAG1 | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.332); catalogued as COSV55055537; called by muse, mutect2, varscan2
- PARP1 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100828846; called by muse, mutect2, varscan2
- PCDH15 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100218578; called by muse, mutect2, varscan2
- PCDHB15 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.021); catalogued as COSV99178874; called by muse, mutect2, varscan2
- PCLO | c.6808G>A p.A2270T | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs780885885, COSV100430365; called by muse, mutect2, varscan2
- PCNX3 | c.3999T>C p.P1333= | Splice Region (SNP) | VAF 13/113 reads (12%) | catalogued as rs757289428, COSV100856245; called by muse, mutect2, varscan2
- PDLIM7 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs1261112196, COSV62883366; called by muse, mutect2, varscan2
- PDS5B | c.3592del p.S1198Vfs*10 | Frame Shift Del (DEL) | VAF 34/226 reads (15%) | catalogued as rs755801132, COSV59734300; called by mutect2, varscan2
- PEPD | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.17); catalogued as rs749796022, COSV99727592; called by muse, mutect2, varscan2
- PHF21A | c.1955del p.P652Lfs*104 (on ENST00000418153 / NM_001101802.3; = p.P606Lfs*104 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 25/81 reads (31%) | catalogued as rs761575760; called by mutect2, pindel, varscan2
- PIWIL1 | c.1122del p.T375Hfs*18 | Frame Shift Del (DEL) | VAF 94/288 reads (33%) | catalogued as rs1298170486, COSV55345426; called by mutect2, varscan2
- PKD1L1 | c.3077C>T p.A1026V | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV99219199; called by muse, mutect2, varscan2
- PKN3 | c.2036_2038del p.K679del | In Frame Del (DEL) | VAF 9/63 reads (14%) | catalogued as rs747170999; called by pindel, varscan2
- PLCH1 | c.4879A>G p.N1627D (on ENST00000340059 / NM_001130960.2; = p.N1619D on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.321); catalogued as COSV100396258; called by muse, mutect2, varscan2
- PLEKHA5 | c.652A>G p.S218G | Missense Mutation (SNP) | VAF 9/265 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100163848; called by muse, mutect2
- PLEKHO1 | c.604T>G p.S202A | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.084); catalogued as COSV99215200; called by muse, mutect2, varscan2
- PLXNA3 | c.49dup p.A17Gfs*39 | Frame Shift Ins (INS) | VAF 21/70 reads (30%) | catalogued as rs782247826; called by mutect2, varscan2
- PLXNC1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99312845; called by muse, mutect2, varscan2
- PNKP | c.4G>T p.G2C | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV100465101; called by muse, varscan2
- PPP1R26 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs754686666, COSV100777993, COSV63356436; called by muse, mutect2, varscan2
- PPP2R1B | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV100232062; called by muse, mutect2, varscan2
- PPP4R1 | c.700G>A p.A234T (on ENST00000400556 / NM_001042388.3; = p.A217T on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs878870696, COSV99553363; called by muse, mutect2
- PPP6R2 | c.2561del p.P854Rfs*23 (on ENST00000216061 / NM_001365836.1; = p.P820Rfs*23 on NM_014678.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 17/83 reads (20%) | catalogued as COSV53291064; called by mutect2, pindel, varscan2
- PRICKLE3 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100889907; called by muse, mutect2, varscan2
- PRKACG | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1451893780, COSV55256044; called by muse, mutect2, varscan2
- PRKAR2B | c.275A>C p.E92A | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.287); catalogued as rs368313660; called by muse, mutect2, varscan2
- PRKCG | c.1604C>T p.S535F | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99668813; called by muse, mutect2, varscan2
- PROKR2 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs746638938, COSV54085675; called by muse, mutect2, varscan2
- PRSS12 | c.1423T>C p.C475R | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1298448272, COSV99628054; called by muse, mutect2
- PSD | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50041693, COSV99192392; called by muse, mutect2, varscan2
- PSPN | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.312); catalogued as COSV99831722; called by muse, mutect2, varscan2
- PTPN21 | c.563T>C p.V188A | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as COSV100161766; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3389C>T p.A1130V | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.178); catalogued as rs369410531; called by muse, mutect2, varscan2
- RAD51D | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as rs201141245; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- RBM19 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99925853; called by muse, mutect2, varscan2
- REEP6 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99278554; called by muse, mutect2, varscan2
- RFX1 | c.741A>T p.R247S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99585971; called by muse, mutect2, varscan2
- RHOT1 | c.1369T>C p.Y457H | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.316); catalogued as COSV100447077; called by muse, mutect2, varscan2
- RIPOR3 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779249727, COSV99246176; called by muse, mutect2, varscan2
- RPAP1 | c.3935T>C p.V1312A | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV99778806; called by muse, mutect2
- RPP25L | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as rs756300443, COSV99426827; called by muse, mutect2, varscan2
- RPRD2 | c.3052C>T p.R1018C | Missense Mutation (SNP) | VAF 31/270 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs746718220, COSV100955009; called by muse, mutect2, varscan2
- RPS2 | c.626T>C p.V209A | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as COSV99238767; called by muse, mutect2, varscan2
- RSPH14 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.97); PolyPhen benign (0.029); catalogued as rs775859719, COSV53267241; called by muse, mutect2, varscan2
- SAFB2 | c.2471dup p.Y825Lfs*9 | Frame Shift Ins (INS) | VAF 28/170 reads (16%) | catalogued as rs759920279; called by mutect2, varscan2
- SAGE1 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.982); catalogued as COSV100186983; called by muse, mutect2, varscan2
- SAMD15 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.083); catalogued as rs761355835, COSV99374887; called by muse, mutect2, varscan2
- SAMD7 | c.1285dup p.C429Lfs*9 | Frame Shift Ins (INS) | VAF 34/139 reads (24%) | catalogued as rs1311379305; called by mutect2, pindel, varscan2
- SAMHD1 | c.1682del p.K561Rfs*35 (on ENST00000262878 / NM_001363729.2; = p.K596Rfs*35 on NM_015474.4) | Frame Shift Del (DEL) | VAF 34/130 reads (26%) | catalogued as rs1215993198; called by mutect2, pindel, varscan2
- SCT | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 43/364 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.636); catalogued as COSV99449200; called by muse, mutect2, varscan2
- SCTR | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs764337321, COSV99191553; called by muse, mutect2, varscan2
- SEC14L3 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs144684185; called by muse, mutect2, varscan2
- SEC16B | c.2597G>A p.S866N | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1222858082, COSV100381460, COSV100382055; called by muse, mutect2
- SF3B3 | c.3472C>T p.R1158W | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270233465, COSV56785524; called by muse, mutect2, varscan2
- SHB | c.1373A>G p.K458R | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100891698; called by muse, mutect2, varscan2
- SHC1 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 31/279 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV58316920; called by muse, mutect2, varscan2
- SLC19A1 | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100229246; called by muse, mutect2
- SLC20A1 | c.1801A>G p.S601G | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs1477896604, COSV99733986; called by muse, mutect2, varscan2
- SLC26A1 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1010411911, COSV56103886; called by muse, mutect2, varscan2
- SLC27A3 | c.280_282del p.E94del | In Frame Del (DEL) | VAF 10/70 reads (14%) | catalogued as rs1259550268; called by mutect2, pindel, varscan2
- SLC27A3 | c.1705C>T p.R569W (on ENST00000271857; = p.R441W on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs772719483, COSV99669875; called by muse, mutect2, varscan2
- SLC9A1 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.213); catalogued as COSV99849477; called by muse, mutect2, varscan2
- SLCO5A1 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs369685189, COSV52663653, COSV99479720; called by muse, mutect2, varscan2
- SLITRK4 | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs1292818470, COSV62023409; called by muse, mutect2, varscan2
- SNTG2 | c.1181G>A p.G394D | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.476); catalogued as COSV57991951; called by muse, mutect2, varscan2
- SOHLH2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV58521287; called by muse, mutect2, varscan2
- SPAG9 | c.2257_2259del p.E753del (on ENST00000262013 / NM_001130528.3; = p.E739del on NM_003971.6) | In Frame Del (DEL) | VAF 11/96 reads (11%) | catalogued as rs763614987; called by pindel, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 12/112 reads (11%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPEG | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1331644780, COSV100404062; called by muse, mutect2, varscan2
- SPRY1 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV100201799; called by muse, mutect2, varscan2
- SPTBN5 | c.6430G>A p.A2144T | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.178); catalogued as rs780365905, COSV100311122; called by muse, mutect2, varscan2
- SRBD1 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); catalogued as COSV99764920; called by muse, mutect2, varscan2
- SRMS | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs775845157, COSV99420433; called by muse, mutect2, varscan2
- SSB | c.578del p.N193Mfs*13 | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | catalogued as rs753297385; called by mutect2, varscan2
- SSTR4 | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs1345914212, COSV54796776, COSV54797912, COSV99658514; called by muse, mutect2, varscan2
- ST18 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200016532; called by muse, mutect2, varscan2
- STK36 | c.1438A>T p.S480C | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV55331433, COSV99831203; called by muse, mutect2, varscan2
- SULT1C3 | c.622-1G>T p.X208_splice | Splice Site (SNP) | VAF 13/150 reads (9%) | catalogued as COSV100227407, COSV61252782; called by muse, mutect2
- SYDE1 | c.635del p.G212Afs*129 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs1214190235; called by mutect2, pindel
- SYNCRIP | c.267G>A p.Q89= | Splice Region (SNP) | VAF 52/90 reads (58%) | catalogued as COSV100784145; called by muse, mutect2, varscan2
- TAF1D | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs774258466, COSV100126809; called by muse, mutect2, varscan2
- TAF1L | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1192501986, COSV54262894; called by muse, varscan2
- TATDN2 | c.1568G>A p.S523N | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.201); catalogued as COSV99813444; called by muse, mutect2, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 52/143 reads (36%) | catalogued as rs745872748; called by mutect2, varscan2
- TDRD5 | c.1800G>T p.E600D | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV99675932; called by muse, mutect2, varscan2
- TEAD1 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100532108; called by muse, mutect2, varscan2
- TEAD3 | c.752T>A p.I251N | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100132353; called by muse, mutect2, varscan2
- TENM2 | c.3181G>A p.E1061K (on ENST00000518659 / NM_001122679.2; = p.E829K on NM_001080428.3) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as rs1464106409, COSV69133110; called by muse, mutect2, varscan2
- TEX10 | c.2675C>T p.T892M | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs371930194; called by muse, mutect2, varscan2
- TEX13A | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 44/159 reads (28%) | catalogued as COSV100781100; called by muse, mutect2, varscan2
- TEX2 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as rs1360731326, COSV51978380, COSV51978860; called by muse, mutect2
- TFAP2D | c.1199C>T p.T400I | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV50412477, COSV50466477, COSV99145834; called by muse, mutect2, varscan2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 154/719 reads (21%) | catalogued as rs782753958; called by mutect2, varscan2
- TGFBRAP1 | c.511C>G p.L171V | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.029); catalogued as COSV99304676; called by muse, mutect2, varscan2
- THSD1 | c.1871T>C p.L624P | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99318826; called by muse, mutect2, varscan2
- THY1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99411441; called by muse, mutect2, varscan2
- TIGD3 | c.578A>C p.D193A | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV99361503; called by muse, mutect2, varscan2
- TIMP1 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV99512155; called by muse, mutect2, varscan2
- TIMP3 | c.595G>C p.A199P | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs757258891, COSV56665522; called by muse, varscan2
- TLE2 | c.1333C>A p.P445T | Missense Mutation (SNP) | VAF 76/203 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99504189; called by muse, mutect2, varscan2
- TLR6 | c.2012T>C p.I671T | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101126261; called by muse, mutect2, varscan2
- TMC5 | c.1147A>G p.R383G (on ENST00000396229 / NM_001105248.1; = p.R137G on NM_024780.5) | Missense Mutation (SNP) | VAF 117/306 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99572324; called by muse, mutect2, varscan2
- TMEM51 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759766365, COSV101051511; called by muse, mutect2, varscan2
- TMTC2 | c.1963C>T p.R655C | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757783753, COSV58262806; called by muse, mutect2, varscan2
- TMUB2 | c.167C>T p.T56I (on ENST00000538716 / NM_001353177.2; = p.T36I on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1179679451, COSV100116114; called by muse, mutect2, varscan2
- TNFRSF6B | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99422878; called by muse, mutect2, varscan2
- TNRC18 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs750353354, COSV101259406; called by muse, mutect2, varscan2
- TOP2A | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 42/214 reads (20%) | catalogued as rs1419834274, COSV101396145; called by muse, mutect2, varscan2
- TOPORS | c.343T>C p.Y115H | Missense Mutation (SNP) | VAF 139/1431 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.327); catalogued as COSV100745145; called by muse, mutect2
- TOR3A | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100751282; called by muse, mutect2, varscan2
- TRIM13 | c.370A>G p.T124A | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100078262; called by muse, mutect2, varscan2
- TRIOBP | c.4436dup p.T1480Hfs*22 | Frame Shift Ins (INS) | VAF 11/74 reads (15%) | catalogued as rs756145453; called by mutect2, varscan2
- TRPM7 | c.4165A>G p.T1389A | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1300265965, COSV100539672; called by muse, mutect2, varscan2
- TRPV2 | c.1329del p.I444Sfs*23 | Frame Shift Del (DEL) | VAF 59/141 reads (42%) | catalogued as COSV100641106; called by mutect2, pindel, varscan2
- TRRAP | c.3430C>T p.R1144C | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1020415712, COSV62844201; called by muse, mutect2, varscan2
- TSPOAP1 | c.4801C>T p.R1601* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | catalogued as COSV99270700; called by muse, mutect2, varscan2
- TTN | c.99931A>G p.R33311G (on ENST00000591111; = p.R25887G on NM_003319.4) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | PolyPhen probably damaging (0.996); catalogued as COSV100604517; called by muse, varscan2
- TTN | c.20593C>T p.R6865W (on ENST00000591111; = p.R5938W on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/127 reads (18%) | PolyPhen benign (0.292); catalogued as rs727504736, COSV100604519, COSV59873082; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UACA | c.3209_3212del p.K1070Sfs*2 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | catalogued as rs760248027; called by pindel, varscan2
- UBD | c.235A>T p.K79* | Nonsense Mutation (SNP) | VAF 49/207 reads (24%) | catalogued as COSV100589594; called by muse, mutect2, varscan2
- UBE4B | c.1329del p.A444Hfs*14 (on ENST00000343090 / NM_001105562.3; = p.A315Hfs*14 on NM_006048.5) | Frame Shift Del (DEL) | VAF 82/202 reads (41%) | catalogued as rs758215455, COSV53529804; called by mutect2, varscan2
- USH2A | c.7873del p.E2625Kfs*16 | Frame Shift Del (DEL) | VAF 22/161 reads (14%) | catalogued as CM149923; called by mutect2, pindel, varscan2
- USP20 | c.1271A>G p.K424R | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100204223; called by muse, mutect2
- VASN | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs757420411, COSV52030940; called by muse, mutect2, varscan2
- VDAC1 | c.689A>G p.D230G | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as COSV99527186; called by muse, mutect2, varscan2
- VWA7 | c.908A>G p.D303G | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100989922; called by muse, mutect2, varscan2
- WAS | c.1288G>T p.G430C | Missense Mutation (SNP) | VAF 56/1390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as CD107125, COSV100939468; called by muse, mutect2
- WDR55 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.743); catalogued as rs367668945; called by mutect2, varscan2
- XAB2 | c.1441T>C p.Y481H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99350325; called by muse, mutect2, varscan2
- ZBBX | c.1975A>G p.R659G | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV100283703; called by muse, mutect2, varscan2
- ZBTB7C | c.989A>C p.D330A | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100134346; called by muse, mutect2, varscan2
- ZDHHC14 | c.410T>A p.I137N | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.366); catalogued as COSV100399154; called by muse, mutect2, varscan2
- ZHX2 | c.1799A>G p.K600R | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); catalogued as rs1382488405, COSV100072844; called by muse, mutect2
- ZIC3 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.06); catalogued as COSV99798724; called by muse, mutect2
- ZNF142 | c.3755dup p.R1253Tfs*15 (on ENST00000411696 / NM_001379660.1; = p.R1053Tfs*15 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 24/120 reads (20%) | catalogued as rs751589999; called by mutect2, varscan2
- ZNF217 | c.1652G>A p.S551N | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as rs958130242, COSV100184364; called by muse, mutect2, varscan2
- ZNF227 | c.2167A>G p.K723E | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV100480333; called by muse, mutect2, varscan2
- ZNF492 | c.1276T>C p.C426R | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1157978654, COSV101513977; called by muse, mutect2, varscan2
- ZNF528 | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV100846639; called by muse, mutect2, varscan2
- ZNF534 | c.340G>A p.G114R (on ENST00000332323 / NM_001143939.3; = p.G101R on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/260 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV99989609; called by muse, mutect2, varscan2
- ZNF568 | c.877C>T p.L293F | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100451234; called by muse, mutect2, varscan2
- ZNF585A | c.1631A>G p.H544R (on ENST00000292841 / NM_001288800.2; = p.H489R on NM_152655.3) | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99492943; called by muse, mutect2, varscan2
- ZNF696 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as COSV57524065; called by muse, mutect2, varscan2
- ZNF91 | c.1949G>A p.R650K | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.187); catalogued as COSV100322535, COSV56081037; called by muse, mutect2, varscan2
- ZRANB3 | c.2148G>C p.Q716H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); catalogued as COSV99923227; called by muse, mutect2, varscan2
- ZSCAN16 | c.818T>C p.F273S | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100481477; called by muse, mutect2
- ZWILCH | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs781621042, COSV57181283; called by muse, mutect2, varscan2
- ZXDC | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs943393981, COSV100306400; called by muse, mutect2
- ACADL | c.478dup p.Q160Pfs*21 | Frame Shift Ins (INS) | VAF 11/90 reads (12%) | called by mutect2, pindel, varscan2
- ADAMTSL1 | c.3464del p.G1155Efs*42 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- ALPK2 | c.4865dup p.L1622Ffs*10 | Frame Shift Ins (INS) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- ANK3 | c.12195del p.K4065Nfs*32 | Frame Shift Del (DEL) | VAF 15/75 reads (20%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.2299dup p.I767Nfs*15 | Frame Shift Ins (INS) | VAF 45/130 reads (35%) | called by mutect2, pindel, varscan2
- AP3B1 | c.2769del p.K923Nfs*4 | Frame Shift Del (DEL) | VAF 21/62 reads (34%) | called by mutect2, varscan2
- APOB | c.8594del p.N2865Ifs*9 | Frame Shift Del (DEL) | VAF 14/105 reads (13%) | called by mutect2, pindel, varscan2
- ARFGAP1 | c.883dup p.S295Ffs*42 | Frame Shift Ins (INS) | VAF 21/92 reads (23%) | called by mutect2, varscan2
- BEX4 | c.159dup p.R54Afs*3 | Frame Shift Ins (INS) | VAF 48/368 reads (13%) | called by mutect2, pindel, varscan2
- CACNA1C | c.5701_5703del p.E1901del (on ENST00000399634 / NM_001167625.1; = p.E1830del on NM_000719.7) | In Frame Del (DEL) | VAF 8/40 reads (20%) | called by pindel, varscan2
- CLK1 | c.723del p.F241Lfs*36 | Frame Shift Del (DEL) | VAF 20/117 reads (17%) | called by mutect2, pindel, varscan2
- CYP2R1 | c.1324del p.S442Pfs*2 | Frame Shift Del (DEL) | VAF 10/103 reads (10%) | called by mutect2, varscan2
- DMRTC2 | c.441del p.K149Rfs*87 | Frame Shift Del (DEL) | VAF 41/241 reads (17%) | called by mutect2, pindel, varscan2
- DNAH6 | c.2115dup p.V706Sfs*7 | Frame Shift Ins (INS) | VAF 19/82 reads (23%) | called by mutect2, pindel, varscan2
- FGFR2 | c.499_519del p.H167_N173del | In Frame Del (DEL) | VAF 17/60 reads (28%) | called by mutect2, pindel, varscan2
- GAB2 | c.1535del p.P512Lfs*19 (on ENST00000361507 / NM_080491.3; = p.P474Lfs*19 on NM_012296.3) | Frame Shift Del (DEL) | VAF 22/161 reads (14%) | called by mutect2, pindel, varscan2
- GIPC1 | c.125del p.G42Afs*56 | Frame Shift Del (DEL) | VAF 14/134 reads (10%) | called by mutect2, pindel
- GPR149 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HIVEP1 | c.4184del p.P1395Hfs*21 | Frame Shift Del (DEL) | VAF 23/141 reads (16%) | called by mutect2, pindel, varscan2
- HLCS | c.1946_1947del p.K649Rfs*99 | Frame Shift Del (DEL) | VAF 48/158 reads (30%) | called by mutect2, pindel, varscan2
- IRF2BP1 | c.1501del p.L501Cfs*10 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | called by mutect2, pindel, varscan2
- KLK6 | c.718del p.T240Pfs*10 | Frame Shift Del (DEL) | VAF 25/139 reads (18%) | called by mutect2, pindel, varscan2
- LAMA1 | c.9084del p.K3028Nfs*13 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | called by mutect2, pindel, varscan2
- LRP1 | c.13387del p.A4463Pfs*2 | Frame Shift Del (DEL) | VAF 14/154 reads (9%) | called by mutect2, pindel
- LRRC8D | c.1864_1873del p.G622Sfs*4 | Frame Shift Del (DEL) | VAF 21/156 reads (13%) | called by mutect2, pindel, varscan2
- MICALL2 | c.437del p.P146Qfs*107 | Frame Shift Del (DEL) | VAF 44/158 reads (28%) | called by mutect2, pindel, varscan2
- MIDN | c.608dup p.V204Gfs*99 | Frame Shift Ins (INS) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- MLLT6 | c.2010-1G>T p.X670_splice | Splice Site (SNP) | VAF 51/155 reads (33%) | called by muse, mutect2, varscan2
- MN1 | c.347dup p.N117Qfs*38 | Frame Shift Ins (INS) | VAF 6/55 reads (11%) | called by mutect2, pindel
- MPP5 | c.721_724del p.R241Ffs*13 | Frame Shift Del (DEL) | VAF 46/116 reads (40%) | called by mutect2, pindel, varscan2
- NDC80 | c.1373_1374del p.Y458Cfs*4 | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- NFASC | c.494del p.P165Rfs*12 (on ENST00000339876 / NM_001378329.1; = p.P159Rfs*12 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 27/133 reads (20%) | called by mutect2, pindel, varscan2
- NHLRC2 | c.1704+5_1704+8del p.X568_splice | Splice Site (DEL) | VAF 30/270 reads (11%) | called by pindel, varscan2
- NYNRIN | c.344del p.P115Lfs*4 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | called by mutect2, varscan2
- OBSL1 | c.427del p.A143Rfs*5 | Frame Shift Del (DEL) | VAF 55/380 reads (14%) | called by mutect2, pindel, varscan2
- OOSP2 | c.373del p.S125Lfs*6 | Frame Shift Del (DEL) | VAF 34/141 reads (24%) | called by mutect2, pindel, varscan2
- PGLS | c.445del p.V149Wfs*38 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel, varscan2
- POLR3E | c.1979del p.N660Ifs*8 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- PPARGC1B | c.408del p.S137Afs*69 | Frame Shift Del (DEL) | VAF 107/407 reads (26%) | called by mutect2, pindel, varscan2
- PSMB3 | c.296+2T>C p.X99_splice | Splice Site (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- PWWP2A | c.1001dup p.E335Gfs*3 | Frame Shift Ins (INS) | VAF 16/124 reads (13%) | called by mutect2, varscan2
- RPL9 | c.158dup p.R54Efs*5 | Frame Shift Ins (INS) | VAF 27/101 reads (27%) | called by mutect2, varscan2
- SAV1 | c.420del p.F140Lfs*49 | Frame Shift Del (DEL) | VAF 42/229 reads (18%) | called by mutect2, varscan2
- SDC2 | c.*2del | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | called by mutect2, pindel, varscan2
- SLC8A1 | c.1230_1232del p.F411del | In Frame Del (DEL) | VAF 12/94 reads (13%) | called by pindel, varscan2
- SMC2 | c.535del p.I179* | Frame Shift Del (DEL) | VAF 55/373 reads (15%) | called by mutect2, varscan2
- SPACA4 | c.44del p.P15Qfs*191 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- SPAG17 | c.4929del p.F1643Lfs*18 | Frame Shift Del (DEL) | VAF 38/292 reads (13%) | called by mutect2, pindel, varscan2
- SPRTN | c.1263del p.F421Lfs*7 | Frame Shift Del (DEL) | VAF 81/418 reads (19%) | called by mutect2, pindel, varscan2
- STAG1 | c.588_590del p.D196del | In Frame Del (DEL) | VAF 26/226 reads (12%) | called by pindel, varscan2
- TENM3 | c.2082del p.T695Rfs*81 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- TMPRSS3 | c.1209del p.L405Wfs*11 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | called by mutect2, pindel, varscan2
- TRIM24 | c.969dup p.G324Rfs*31 | Frame Shift Ins (INS) | VAF 77/608 reads (13%) | called by mutect2, varscan2
- USP44 | c.550dup p.I184Nfs*19 | Frame Shift Ins (INS) | VAF 35/97 reads (36%) | called by mutect2, pindel, varscan2
- ZNF292 | c.3470del p.L1157Cfs*5 | Frame Shift Del (DEL) | VAF 30/72 reads (42%) | called by mutect2, pindel, varscan2
- ABCB10 | c.1440G>T p.G480= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV100747904; called by muse, mutect2, varscan2
- ABR | c.2571C>T p.T857= (on ENST00000302538 / NM_021962.5; = p.T820= on NM_001092.5) | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs375629677; called by muse, mutect2, varscan2
- ACADSB | c.1194C>T p.Y398= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV100715135; called by muse, varscan2
- ADAMTS19 | c.3189T>C p.R1063= | Silent (SNP) | VAF 17/145 reads (12%) | catalogued as COSV99177130; called by muse, mutect2, varscan2
- ADGRB1 | c.2868C>T p.G956= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as rs770399870, COSV60097112; called by muse, mutect2, varscan2
- AHNAK | c.12084T>C p.G4028= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV99946765; called by muse, mutect2, varscan2
- APOBEC3G | c.750C>T p.H250= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as rs1311285643, COSV101349064; called by muse, mutect2, varscan2
- ARL6 | c.66C>T p.C22= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV100256436, COSV60118116; called by muse, mutect2, varscan2
- ASTN1 | c.1833C>T p.C611= | Silent (SNP) | VAF 31/248 reads (13%) | catalogued as COSV99921082; called by muse, mutect2, varscan2
- BASP1 | c.198C>T p.A66= | Silent (SNP) | VAF 60/193 reads (31%) | catalogued as rs367590306, COSV100493671; called by muse, mutect2, varscan2
- BCORL1 | c.4731T>C p.H1577= | Silent (SNP) | VAF 8/206 reads (4%) | catalogued as COSV99499069; called by muse, mutect2
- BRINP1 | c.366C>A p.I122= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV99775062; called by muse, mutect2, varscan2
- BROX | c.549C>T p.Y183= | Silent (SNP) | VAF 46/470 reads (10%) | catalogued as rs368189414; called by muse, mutect2
- C20orf96 | c.966G>A p.E322= (on ENST00000360321 / NM_153269.3; = p.E321= on NM_080571.1) | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as rs1568489810, COSV100826690; called by muse, mutect2, varscan2
- CA14 | c.222C>A p.T74= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV100809913; called by muse, mutect2
- CA5B | c.657C>T p.C219= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as rs751204543, COSV100590712; called by muse, mutect2, varscan2
- CACNG2 | c.822C>T p.S274= | Silent (SNP) | VAF 21/134 reads (16%) | catalogued as rs1327592769, COSV55636063; called by muse, mutect2, varscan2
- CAMK2B | c.969G>A p.P323= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs748787629, COSV99322934; called by muse, mutect2, varscan2
- CARD10 | c.969T>C p.H323= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99324818; called by muse, mutect2, varscan2
- CD93 | c.1674C>A p.P558= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99849085; called by muse, mutect2, varscan2
- CDRT1 | c.2256G>A p.V752= | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as rs542008653, COSV100599841; called by muse, mutect2, varscan2
- CELSR1 | c.3960C>T p.S1320= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as rs201238170, COSV53101927; called by muse, mutect2, varscan2
- CHTF18 | c.1923T>C p.S641= | Silent (SNP) | VAF 52/100 reads (52%) | catalogued as COSV99242637; called by muse, mutect2, varscan2
- CLMP | c.162C>T p.T54= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as rs767487653, COSV71650751; called by muse, mutect2, varscan2
- CNNM1 | c.21G>A p.A7= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100763816; called by muse, mutect2, varscan2
- COA8 | c.369C>T p.G123= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99914789; called by muse, mutect2, varscan2
- COL23A1 | c.1515C>G p.G505= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV101178455; called by muse, mutect2, varscan2
- CORO1A | c.555C>T p.S185= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs745531321, COSV99531905; called by muse, mutect2, varscan2
- COX10 | c.822C>T p.Y274= | Silent (SNP) | VAF 22/151 reads (15%) | called by muse, varscan2
- CP | c.885C>T p.H295= | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as rs766821938, COSV99223963; ClinVar: likely benign; called by muse, mutect2, varscan2
- CRACD | c.1149C>T p.P383= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as COSV99948965; called by muse, mutect2, varscan2
- CTNND1 | c.2814C>T p.D938= (on ENST00000399050 / NM_001085458.2; = p.D911= on NM_001331.3) | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as rs773613029, COSV100649982; called by muse, mutect2, varscan2
- CUL9 | c.7371C>A p.S2457= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as COSV99335167; called by muse, mutect2, varscan2
- CYP17A1 | c.345T>C p.A115= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100882091; called by muse, mutect2, varscan2
- DCLK1 | c.84C>T p.N28= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs373323934; called by muse, mutect2, varscan2
- DGKQ | c.1512C>T p.G504= | Silent (SNP) | VAF 53/182 reads (29%) | catalogued as rs747177946, COSV99892544; called by muse, mutect2, varscan2
- DNA2 | c.3102C>T p.N1034= | Silent (SNP) | VAF 6/136 reads (4%) | catalogued as rs1392954514, COSV100622481; called by muse, mutect2
- DNM1 | c.2214G>A p.A738= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV100359763; called by muse, mutect2, varscan2
- DOCK6 | c.4684C>T p.L1562= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV99625276; called by muse, mutect2, varscan2
- DOK2 | c.789G>A p.S263= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs779549207, COSV52388547; called by muse, mutect2, varscan2
- DPYSL4 | c.747G>A p.P249= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as rs377151543; called by muse, mutect2, varscan2
- DYRK4 | c.804G>A p.R268= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as COSV99155975; called by muse, mutect2, varscan2
- EFCAB6 | c.147T>C p.A49= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV99413052; called by muse, mutect2, varscan2
- ETV5 | c.450T>C p.F150= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV100112213; called by muse, mutect2, varscan2
- EVPL | c.3960C>T p.H1320= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs760754752, COSV56911786; called by muse, mutect2, varscan2
- FAM120B | c.2307C>A p.A769= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV99379196; called by muse, mutect2, varscan2
- FBN3 | c.7398C>T p.G2466= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs759336128, COSV99560541; called by muse, mutect2, varscan2
- FBXL16 | c.1248G>A p.K416= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV99556519; called by muse, mutect2, varscan2
- FBXO5 | c.222C>T p.Y74= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as rs143943044; called by muse, mutect2, varscan2
- FBXW5 | c.1293C>T p.A431= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs372957829; called by muse, mutect2, varscan2
- FCER1G | c.228C>T p.Y76= | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as rs745961564, COSV99248177; called by muse, mutect2, varscan2
- FMNL1 | c.2676G>A p.P892= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as rs1046843775, COSV58957013; called by muse, mutect2, varscan2
- FTMT | c.270G>A p.A90= | Silent (SNP) | VAF 37/138 reads (27%) | catalogued as COSV58419657, COSV58420171; called by muse, mutect2, varscan2
- FURIN | c.1977C>T p.C659= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV99184651; called by muse, mutect2, varscan2
- FZD10 | c.828C>T p.G276= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs1566096392, COSV99969346; called by muse, mutect2, varscan2
- GABRB2 | c.1209C>T p.N403= (on ENST00000274547; = p.N365= on NM_000813.3) | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV50968107; called by muse, mutect2, varscan2
- GDAP1 | c.720C>T p.C240= | Silent (SNP) | VAF 21/185 reads (11%) | catalogued as rs367790253; ClinVar: likely benign; called by muse, mutect2, varscan2
- GLI3 | c.1659C>T p.C553= | Silent (SNP) | VAF 45/167 reads (27%) | catalogued as rs532041527, COSV101229802; called by muse, mutect2, varscan2
- GPR176 | c.1257G>A p.A419= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs758625482, COSV54445130; called by muse, mutect2, varscan2
- GRIA3 | c.396C>T p.D132= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs192636764, COSV99989640; called by muse, mutect2, varscan2
- GSS | c.870T>C p.H290= | Silent (SNP) | VAF 35/251 reads (14%) | catalogued as COSV99404342; called by muse, mutect2, varscan2
- GYS2 | c.1752C>A p.I584= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV99679646; called by muse, mutect2, varscan2
- H2BC7 | c.6T>C p.P2= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV100587153; called by muse, mutect2, varscan2
- HBP1 | c.1449C>T p.Y483= | Silent (SNP) | VAF 44/190 reads (23%) | catalogued as rs538604670, COSV99753149; called by muse, mutect2, varscan2
- HDX | c.813C>T p.S271= | Silent (SNP) | VAF 34/155 reads (22%) | catalogued as rs755004554, COSV52975785, COSV99946801; called by muse, mutect2, varscan2
- HGFAC | c.387C>T p.H129= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as rs1560191414, COSV100122770; called by muse, mutect2, varscan2
- HIPK3 | c.1062T>C p.T354= | Silent (SNP) | VAF 19/159 reads (12%) | catalogued as COSV100305624; called by muse, mutect2, varscan2
- HMGCS2 | c.1176G>A p.S392= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as COSV65568070; called by muse, mutect2, varscan2
- HR | c.3183C>T p.D1061= | Silent (SNP) | VAF 45/118 reads (38%) | catalogued as rs371739727; called by muse, mutect2, varscan2
- HYAL4 | c.711C>T p.C237= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as rs767709879, COSV99772170; called by muse, mutect2, varscan2
- IFRD2 | c.1068G>T p.R356= | Silent (SNP) | VAF 94/172 reads (55%) | catalogued as COSV100269401; called by muse, mutect2, varscan2
- IGKV1D-43 | c.297C>T p.S99= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as rs773530787; called by muse, mutect2, varscan2
- IL3RA | c.849C>T p.S283= | Silent (SNP) | VAF 16/286 reads (6%) | catalogued as rs746729235, COSV58431554; called by muse, mutect2
- INA | c.612C>T p.D204= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100878605; called by muse, mutect2
- INSYN1 | c.42C>T p.D14= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs146110202, COSV101138736; called by muse, mutect2, varscan2
- KCNA4 | c.60T>C p.G20= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100068803; called by muse, mutect2, varscan2
- KCNV2 | c.1104C>T p.S368= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs960100570, COSV101172558; called by muse, mutect2, varscan2
- KIAA0232 | c.3789A>G p.G1263= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV100300607; called by muse, mutect2
- KRT12 | c.1128C>T p.A376= | Silent (SNP) | VAF 51/140 reads (36%) | catalogued as rs373922617, COSV52430127; called by muse, mutect2, varscan2
- KRT79 | c.459C>T p.F153= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as rs376301539, COSV57941207; called by muse, mutect2, varscan2
- KRTAP5-11 | c.138C>T p.C46= | Silent (SNP) | VAF 30/141 reads (21%) | catalogued as COSV100651777; called by muse, mutect2, varscan2
- LENG8 | c.552G>A p.Q184= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV100457324, COSV58730455; called by muse, mutect2, varscan2
- LRP1B | c.2961C>T p.C987= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs146639012, COSV67257386; called by muse, mutect2, varscan2
- LRP5 | c.3309C>T p.R1103= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs141446007; called by muse, mutect2, varscan2
- LRRC56 | c.921C>A p.G307= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV54242067, COSV99529886; called by muse, mutect2, varscan2
- MAPKAPK5 | c.1287C>T p.C429= (on ENST00000551404 / NM_139078.3; = p.C427= on NM_003668.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV101612308; called by muse, mutect2, varscan2
- MCTS1 | c.108T>C p.I36= | Silent (SNP) | VAF 117/456 reads (26%) | catalogued as COSV100989148; called by muse, mutect2, varscan2
- MED4 | c.102T>C p.L34= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99319914; called by muse, mutect2
- MIB2 | c.2979C>T p.G993= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100598834; called by muse, mutect2, varscan2
- MINDY2 | c.1707T>A p.A569= | Silent (SNP) | VAF 46/197 reads (23%) | catalogued as rs936360803, COSV57508022; called by muse, mutect2, varscan2
- MLXIP | c.2592G>A p.A864= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs561027162, COSV100038613; called by muse, mutect2, varscan2
- MRGPRX4 | c.342C>T p.S114= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs774403101, COSV58591158; called by muse, mutect2, varscan2
- MUC2 | c.2460C>T p.S820= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as rs376792696; called by muse, mutect2, varscan2
- MYO3A | c.2499A>G p.A833= | Silent (SNP) | VAF 37/241 reads (15%) | catalogued as COSV56354492; called by muse, mutect2, varscan2
- NAPRT | c.1248G>A p.T416= | Silent (SNP) | VAF 59/284 reads (21%) | catalogued as rs143442304; called by muse, mutect2, varscan2
- NES | c.3960G>A p.R1320= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as rs1255707363, COSV100957829; called by muse, mutect2
- NSF | c.1776G>A p.A592= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs752142007, COSV99833764; called by muse, mutect2, varscan2
- NUP153 | c.2967A>G p.L989= | Silent (SNP) | VAF 59/185 reads (32%) | catalogued as COSV100020119; called by muse, mutect2, varscan2
- NYNRIN | c.471T>C p.A157= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV101230563; called by muse, mutect2, varscan2
- OR4C13 | c.708T>C p.S236= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as rs145221317, COSV101634232, COSV73648884; called by muse, mutect2, varscan2
- OR51I2 | c.573T>C p.D191= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100413365; called by muse, mutect2, varscan2
- OR6C75 | c.27C>T p.D9= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs779669359, COSV100595306; called by muse, mutect2
- OR7D4 | c.834C>T p.Y278= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs771972062, COSV58071421; called by muse, mutect2, varscan2
- OR8J3 | c.75T>C p.I25= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV100040737; called by muse, mutect2, varscan2
- PAQR9 | c.420C>T p.H140= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV100503758; called by muse, mutect2, varscan2
- PDE4DIP | c.1401T>C p.L467= | Silent (SNP) | VAF 17/178 reads (10%) | catalogued as COSV100518301; called by muse, mutect2, varscan2
- PDE6A | c.2130C>T p.I710= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as rs750000569, COSV54927344; called by muse, mutect2, varscan2
- PER3 | c.2298C>T p.N766= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs767649662, COSV62708110; called by muse, mutect2, varscan2
- PEX26 | c.42G>A p.G14= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as rs758778915, COSV100299060; called by muse, mutect2, varscan2
- PHC1 | c.2358C>T p.S786= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs754172941, COSV101418562; called by muse, mutect2, varscan2
- PITPNM2 | c.1560C>A p.S520= | Silent (SNP) | VAF 54/97 reads (56%) | catalogued as COSV99758639; called by muse, mutect2, varscan2
- PLPP2 | c.498G>A p.S166= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as rs751500921, COSV99514600, COSV99514779; called by muse, mutect2, varscan2
- PM20D1 | c.627C>T p.G209= | Silent (SNP) | VAF 111/332 reads (33%) | catalogued as rs144962279; called by muse, mutect2, varscan2
- PPARGC1B | c.2667C>T p.H889= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs566927619, COSV100494632; called by muse, mutect2, varscan2
- PPAT | c.468G>A p.A156= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs746387194, COSV99947175; called by muse, mutect2, varscan2
- PPP1R16A | c.1437T>C p.P479= | Silent (SNP) | VAF 16/168 reads (10%) | catalogued as COSV99477527; called by muse, mutect2
- PPP1R26 | c.63G>A p.P21= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs769096725, COSV63356722; called by muse, mutect2, varscan2
- RBM14 | c.381C>T p.A127= | Silent (SNP) | VAF 60/235 reads (26%) | catalogued as rs1303418529, COSV100036632; called by muse, mutect2, varscan2
- ROGDI | c.165C>T p.P55= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs1455879564, COSV100424128, COSV100424168; called by muse, mutect2, varscan2
- RP2 | c.525T>C p.H175= | Silent (SNP) | VAF 9/226 reads (4%) | catalogued as COSV54463143; called by muse, mutect2
- RPS6KA3 | c.105G>A p.E35= | Silent (SNP) | VAF 32/270 reads (12%) | catalogued as COSV101092858; called by muse, varscan2
- RSRP1 | c.582C>T p.N194= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV99682611; called by muse, mutect2, varscan2
- RTTN | c.4362T>C p.D1454= | Silent (SNP) | VAF 43/277 reads (16%) | catalogued as rs1370541723, COSV99731853; called by muse, mutect2, varscan2
- SEMA4F | c.1365G>A p.L455= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV100335905; called by muse, mutect2, varscan2
- SFRP4 | c.453G>A p.K151= | Silent (SNP) | VAF 69/233 reads (30%) | catalogued as COSV101460885; called by muse, mutect2, varscan2
- SH2B2 | c.432C>T p.L144= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV100159319; called by muse, mutect2, varscan2
- SIRT1 | c.570A>G p.Q190= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs762335935, COSV99281695; called by muse, mutect2, varscan2
- SIX4 | c.426A>G p.L142= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV99382163; called by muse, mutect2, varscan2
- SLC35B4 | c.892C>T p.L298= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as rs750676303, COSV101043071; called by muse, mutect2, varscan2
- SLF2 | c.1593C>T p.A531= | Silent (SNP) | VAF 17/128 reads (13%) | catalogued as rs1481435595, COSV99488907; called by muse, mutect2, varscan2
- SMAP1 | c.621C>T p.S207= (on ENST00000370455 / NM_001044305.3; = p.S180= on NM_021940.5) | Silent (SNP) | VAF 141/413 reads (34%) | catalogued as COSV100391046; called by muse, mutect2, varscan2
- SNAI2 | c.339A>G p.L113= | Silent (SNP) | VAF 42/185 reads (23%) | catalogued as rs1413333110, COSV99194949; called by muse, mutect2, varscan2
- SOX3 | c.786G>A p.T262= | Silent (SNP) | VAF 20/157 reads (13%) | catalogued as COSV100983683; called by muse, mutect2, varscan2
- SP110 | c.2028T>C p.G676= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs770898382, COSV99283269; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPG21 | c.303T>C p.D101= | Silent (SNP) | VAF 42/201 reads (21%) | catalogued as COSV99200184; called by muse, mutect2, varscan2
- SREBF1 | c.300C>T p.P100= | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as COSV99888640; called by muse, mutect2, varscan2
- SRGAP2 | c.3051C>T p.I1017= (on ENST00000624873 / NM_001170637.4; = p.I1018= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 87/307 reads (28%) | catalogued as rs1432374451, COSV55338692; called by muse, mutect2, varscan2
- STAG2 | c.1392G>A p.L464= | Silent (SNP) | VAF 13/124 reads (10%) | catalogued as COSV99492956; called by muse, mutect2, varscan2
- SYMPK | c.3753A>T p.G1251= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV99679701, COSV99680037; called by muse, mutect2, varscan2
- TENM1 | c.7029C>T p.G2343= | Silent (SNP) | VAF 24/204 reads (12%) | catalogued as rs774343710, COSV64448084; called by muse, mutect2, varscan2
- TFRC | c.52T>C p.L18= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs1398987655, COSV100786430; called by muse, mutect2
- TMEM163 | c.309G>A p.A103= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as rs543616754, COSV56108314; called by muse, mutect2, varscan2
- TMEM92 | c.258G>A p.P86= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs563916883, COSV100305129; called by muse, mutect2, varscan2
- TNK1 | c.937C>T p.L313= | Silent (SNP) | VAF 32/62 reads (52%) | catalogued as COSV61171137; called by muse, mutect2, varscan2
- TPTE2 | c.1233T>C p.C411= (on ENST00000400230 / NM_199254.2; = p.C334= on NM_130785.3) | Silent (SNP) | VAF 69/224 reads (31%) | catalogued as rs1290752711, COSV55020611; called by muse, mutect2, varscan2
- TRAF3 | c.1389C>T p.D463= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs752675828, COSV100693424; called by muse, mutect2, varscan2
- TTI2 | c.1356C>T p.S452= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as rs145192530; called by muse, mutect2, varscan2
- VARS1 | c.2211T>G p.T737= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as COSV100791796; called by muse, mutect2
- VPS52 | c.40C>T p.L14= | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as COSV101460421; called by muse, mutect2, varscan2
- WDR36 | c.2223T>C p.Y741= | Silent (SNP) | VAF 45/194 reads (23%) | catalogued as COSV101550958; called by muse, mutect2, varscan2
- ZFHX4 | c.771T>C p.P257= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as COSV99261010; called by muse, varscan2
- ZNF394 | c.717T>C p.H239= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV100529856; called by muse, mutect2, varscan2
- ZNF536 | c.1041C>T p.C347= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs1200857229, COSV62833046; called by muse, mutect2, varscan2
- ZNF793 | c.927A>G p.R309= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV101495647; called by muse, mutect2, varscan2
- AGPAT4 | c.843+2293_843+2294del | Intron (DEL) | VAF 5/46 reads (11%) | called by pindel, varscan2
- DCX | c.-22-396G>T | Intron (SNP) | VAF 26/580 reads (4%) | catalogued as COSV100576332; called by muse, mutect2
- DELEC1 | n.623T>C | RNA (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100927019; called by muse, mutect2, varscan2
- FRMPD2B | n.1145_1146dup | RNA (INS) | VAF 16/138 reads (12%) | called by mutect2, varscan2
- L1CAM | chrX:153887002 G>A | 5'Flank (SNP) | VAF 102/350 reads (29%) | called by muse, varscan2
- MYADM | chr19:53874369 C>T | 3'Flank (SNP) | VAF 13/78 reads (17%) | catalogued as rs752025084, COSV100425107, COSV61239143; called by muse, mutect2, varscan2
- OBSCN | c.18662-2662C>T | Intron (SNP) | VAF 48/412 reads (12%) | catalogued as rs867970204, COSV52778041; called by muse, mutect2, varscan2
- WNK2 | chr9:93318529 ins C | 3'Flank (INS) | VAF 19/117 reads (16%) | catalogued as rs1403859834; called by mutect2, pindel, varscan2
